Surgical pathology report (de-identified scan), TCGA case TCGA-BF-AAP2, project TCGA-SKCM (Skin Cutaneous Melanoma), tissue source site Cureline, specimen TCGA-BF-AAP2-01A (Primary Tumor).

Case #

Patient: **Age (years):** **Gender:** Male

Clinical diagnosis: Melanoma

Date of procurement:

Sample:

Gross description:

The material presented – Skin from right hand, surgical resection

Microscopic description:

Received material is ulcerated pigment epithelioid melanoma from right hand,
Clark-III, Breslow - 3 mm, Stage 2B, Grade 3, T3, N0, M0.

Final diagnosis: Epithelioid melanoma

ICD-O-3
Melanoma, epithelioid cell 8771/3
Site: Skin R hand C44.6
4/22/14

Pw TSS, non-glabrous

Confidential

Source: NCI Genomic Data Commons file ac025fdd-ff61-4e0c-a53e-31ca39a1735b (TCGA-BF-AAP2.1D0FBB3F-88FE-49CD-9744-CA64674EB593.PDF), Data Release 46.0 - August 10, 2026; text from the OCR (chandra-v1.5.0).